Gene-level copy-number profile of tumor specimen TCGA-23-1117-01A from TCGA case TCGA-23-1117, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 43.0 years (15,690 days).
Specimen TCGA-23-1117-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.30fd69a7-2999-4688-a8fd-94924b2dbc9d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-23-1117-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2074e39f-6579-49b5-a377-40af3890e7a9

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 778; copy number 2: 15,681; copy number 3: 18,394; copy number 4: 19,472; copy number 5: 3,241; copy number 6: 1,003; copy number 7: 225; copy number 8: 657; copy number 9: 340; copy number 11: 12; copy number 12: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-23-1117-01A-02D-0428-01): tumor purity 0.69, ploidy 3.31, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:41,739,369–41,767,089, 3 genes: RIPK4, AP001615.1, MIR6814.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,245 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:139,323,921–140,221,485, 12 genes, copy number 8: AC013265.1, AC062021.1, AC016710.1, SNORA72, MRPS18BP2, RPL9P13, AC078851.1, RN7SL283P, LINC01853, MTCO1P44, MTND2P19, MTND1P27.
- chr2:140,234,737–140,234,923, 1 gene, copy number 8: AC092156.1.
- chr2:171,687,409–172,736,206, 21 genes, copy number 8: DYNC1I2, SLC25A12, RNU6-182P, HAT1, METAP1D, DLX1, DLX2, DLX2-DT, AC104088.1, AC104088.3, AC104088.2, AC078883.3, ITGA6, AC078883.2, ITGA6-AS1, AC078883.1, PDK1, Y_RNA, AC018712.1, RAPGEF4-AS1, AC018712.2.
- chr3:136,778,181–137,011,085, 9 genes, copy number 8: AC096992.3, AC096992.1, SLC35G2, NCK1-DT, AC096992.2, NCK1, RAD51AP1P1, IL20RB, IL20RB-AS1.
- chr3:138,889,255–139,782,699, 25 genes, copy number 7 (within-gene range 5–7): ATP5MC1P3, LINC01391, FOXL2, FOXL2NB, PRR23A, MRPS22, PRR23B, PRR23C, RPL7L1P7, BPESC1, PISRT1, AC119740.1, AC024933.2, AC024933.1, COPB2, U6, AC046134.2, RBP2, AC097103.1, ACTG1P1, RBP1, NMNAT3, AC046134.1, RN7SKP124, RN7SL724P.
- chr4:40,423,267–40,630,875, 1 gene, copy number 7 (within-gene range 2–7): RBM47.
- chr4:40,502,040–41,216,714, 8 genes, copy number 7–11 (within-gene range 6–11): MIR4802, AC131953.2, NSUN7, ARL4AP2, APBB2, AC131953.1, Y_RNA, RNA5SP160.
- chr6:19,837,370–20,317,739, 6 genes, copy number 8 (within-gene range 4–8): ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2.
- chr8:86,707,547–118,111,826, 428 genes, copy number 7–12 (within-gene range 6–12) (broad region; genes not listed).
- chr8:123,157,729–125,367,120, 63 genes, copy number 7 (broad region; genes not listed).
- chr9:76,915,615–77,073,295, 7 genes, copy number 9: AL353637.2, DNAJB5P1, LYPLA2P3, AL353637.1, FOXB2, ATP5MFP3, RFC5P1.
- chr9:108,252,154–108,950,744, 9 genes, copy number 7: AL353742.1, AL669983.1, AL358779.1, RPL36AP35, AL359692.1, ACTL7B, ACTL7A, ELP1, ABITRAM.
- chr10:44,712–13,668,445, 242 genes, copy number 8 (broad region; genes not listed).
- chr10:13,675,646–13,756,200, 4 genes, copy number 8: AL157392.4, AL157392.1, RNA5SP301, AL157392.2.
- chr10:80,454,166–86,525,101, 60 genes, copy number 7: TSPAN14, AC021028.1, SH2D4B, LINC02655, RPS7P9, AC027673.1, FARSBP1, WARS2P1, RPA2P2, AL096706.1, NRG3, AC010157.2, AC010157.1, NRG3-AS1, RNU6-441P, RNU6-478P, MARK2P15, LINC02650, AC069540.2, AC069540.1, RNU6-129P, AL390786.1, RNU1-65P, HMGN2P8, AL603756.1, GHITM, CERNA2, C10orf99, CDHR1, LRIT2, RGR, LRIT1, LINC00858, CCSER2, RPL12P29, TNPO1P1, CACYBPP1, RPS3AP5, AL358787.2, LINC01519, AL358787.1, LINC02647, AC025428.1, LINC01520, AL731532.1, RNU6-325P, AL731532.2, GRID1-AS1, GRID1, AC022028.3, AC022028.2, RN7SKP238, AC022028.1, RNA5SP322, MIR346, AL844892.2, AL844892.1, WAPL, RNU6-780P, AL731569.1.
- chr10:118,241,468–119,033,730, 12 genes, copy number 8: AL354863.1, FAM204A, LINC00867, SLC25A18P1, PRLHR, TOMM22P5, CACUL1, AL139407.1, AL157388.1, RPL17P36, LDHAP5, NANOS1.
- chr14:81,246,295–82,030,349, 13 genes, copy number 7: DYNLL1P1, UNGP3, STON2, AL121769.1, DYNLL1P2, LINC02308, SEL1L, LINC01467, EEF1A1P2, LINC02311, AL355838.1, RPL9P6, EIF3LP1.
- chr17:72,627,231–72,644,490, 2 genes, copy number 7: RPL32P33, AC080037.2.
- chr17:72,663,823–72,664,152, 1 gene, copy number 7: RN7SKP180.
- chr20:50,794,894–64,313,132, 321 genes, copy number 7–11 (within-gene range 4–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 778. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
